Gene-level copy-number profile of tumor specimen TCGA-24-2024-01A from TCGA case TCGA-24-2024, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.5 years (26,476 days).
Specimen TCGA-24-2024-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7faa8eaf-a19f-40df-bc1c-2dddd37dac9a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2024-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bc86aa45-624d-458f-8074-8110f95df6db

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 17,834; copy number 2: 37,994; copy number 3: 3,964.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2024-01A-02D-0663-01): tumor purity 0.91, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–738,106, 19 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1.
- chr8:738,548–1,019,704, 3 genes: AC100797.4, AC026950.2, AC129915.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 15,414. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
